Somatic mutation profile of tumor specimen TARGET-10-PATFRM-09A (aliquot TARGET-10-PATFRM-09A-01D) from TARGET case TARGET-10-PATFRM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 18.3 years (6,696 days).
Specimen TARGET-10-PATFRM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93a5f354-506d-484b-aa0e-8ff49fc6b10b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATFRM-10A (Blood Derived Normal), aliquot TARGET-10-PATFRM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f4d78e6-2edf-4a2d-b46a-7dd1d6e144e1

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Frame Shift Ins 2, RNA 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP192 | c.2888G>A p.S963N | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV58072152; called by muse, mutect2, varscan2
- CFAP44 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV55616944; called by muse, mutect2, varscan2
- MYOM1 | c.3041T>C p.M1014T | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.46); PolyPhen benign (0.102); catalogued as rs1429348821, COSV55303388; called by muse, mutect2, varscan2
- PCDH17 | c.1067T>C p.V356A | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV64980917; called by muse, mutect2, varscan2
- WT1 | c.1092_1093insCCCTG p.T365Pfs*2 | Frame Shift Ins (INS) | VAF 18/20 reads (90%) | catalogued as COSV100189314, COSV60066218, COSV60070964, COSV60071625, COSV60074596, COSV60085914, COSV60087225; called by mutect2, varscan2
- BCORL1 | c.2860_2861insGG p.E954Gfs*22 | Frame Shift Ins (INS) | VAF 9/44 reads (20%) | called by mutect2, pindel, varscan2
- DNMBP | c.3100G>C p.E1034Q | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- GIGYF1 | c.2952G>A p.L984= | Silent (SNP) | VAF 13/21 reads (62%) | called by muse, mutect2, varscan2
- KCNT1 | c.1173G>A p.T391= (on ENST00000488444; = p.T410= on NM_020822.3) | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs778178642, COSV53703072; called by muse, mutect2, varscan2
- CROCCP2 | n.2314A>C | RNA (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2
- GFPT2 | c.7+833A>G | Intron (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
